Gene-level copy-number profile of tumor specimen TCGA-34-A5IX-01A from TCGA case TCGA-34-A5IX, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 80.5 years (29,391 days).
Specimen TCGA-34-A5IX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.172ef0e7-bd87-4a0f-9a86-ef9300204ed5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-A5IX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3eabb4a6-0418-4ddd-8382-66a3dfbe8873

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 109; copy number 2: 23,863; copy number 3: 10,966; copy number 4: 19,402; copy number 5: 4,539; copy number 6: 853; copy number 7: 6; copy number 9: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-A5IX-01A-12D-A27J-01): tumor purity 0.36, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:88,048,135–89,652,144, 41 genes: MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1.
- chr11:101,915,010–102,001,062, 1 gene: CEP126.
- chr12:12,049,844–12,289,329, 8 genes: BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P.
- chr13:63,183,096–63,513,393, 2 genes: LINC00376, AL359208.1.
- chr16:3,725,054–3,950,586, 3 genes (within-gene range 0–3): CREBBP, AC007151.1, LINC02861.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,424 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–99,637,308, 82 genes, copy number 5 (broad region; genes not listed).
- chr3:118,004,819–198,222,513, 1,473 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:147,060,613–149,896,233, 32 genes, copy number 5–9 (within-gene range 2–9): AC097450.1, MIR548G, AC010683.1, PRMT5P1, EDNRA, AC093908.1, GTF2F2P1, LINC02507, AC093835.1, TMEM184C, PRMT9, ARHGAP10, RNA5SP165, MIR4799, RN7SL254P, AC115621.1, NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355, IQCM, AC108168.1, AC093893.1.
- chr4:162,022,733–163,266,583, 10 genes, copy number 5: AC023136.1, MTHFD2P4, TOMM22P4, AC021134.1, AC021134.2, AC084752.1, MIR4454, AC022272.1, NAF1, AC079238.1.
- chr4:188,091,273–190,092,279, 47 genes, copy number 6 (within-gene range 2–6): TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr7:4,511,959–35,379,675, 527 genes, copy number 5 (broad region; genes not listed).
- chr7:35,614,650–47,254,558, 234 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:49,230,137–159,233,377, 2,146 genes, copy number 5 (broad region; genes not listed).
- chr8:150,584–4,994,972, 65 genes, copy number 5–6 (within-gene range 0–6) (broad region; genes not listed).
- chr8:5,506,068–5,911,236, 6 genes, copy number 7: AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159.
- chr8:6,403,551–12,719,190, 275 genes, copy number 6 (broad region; genes not listed).
- chr8:111,093,263–145,066,685, 527 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
